TCGA case TCGA-2G-AAFE — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: Erasmus MC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1d25c24e-bd3c-4023-85c1-b158f76324f1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 37 years; Year of birth: 1963; Vital status: Alive.

Diagnoses (4)
1. Seminoma, NOS (the primary disease): ICD-O-3 morphology code: 9061/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 37.9 years (13,845 days); Year of diagnosis: 2001; Method of diagnosis: Orchiectomy; AJCC staging edition: 5th; AJCC clinical T: T2; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage IIA; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 4,702 days (12.9 years); Ajcc serum tumor markers: S1.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Pathology details: Intratubular germ cell neoplasia present: Yes; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Etoposide + Ifosfamide; Treatment intent type: Adjuvant; Days to treatment start: 644 days (1.8 years); Days to treatment end: 686 days (1.9 years); Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Mixed germ cell tumor: Tissue or organ of origin: Testis, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 23.7 years (8,666 days); Days to diagnosis: -5,179 days (-14.2 years); AJCC staging edition: 2nd; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Bleomycin + Cisplatin + Etoposide; Days to treatment start: -5,138 days (-14.1 years).
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: Radiation Therapy, NOS.
3. Recurrence of diagnosis 1 (Seminoma, NOS), site: Intra-abdominal lymph nodes. Age at diagnosis: 39.6 years (14,462 days); Days to diagnosis: 617 days (1.7 years); Prior treatment: Yes.
4. Recurrence of diagnosis 1 (Seminoma, NOS), site: Intra-abdominal lymph nodes. Age at diagnosis: 49.6 years (18,115 days); Days to diagnosis: 4,270 days (11.7 years); Prior treatment: Yes.

Follow-up (5 entries)
- Day 617 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to recurrence: 617 days (1.7 years).
- Days to follow up: 4,092 days (11.2 years); Disease response: Tumor Free.
- Day 4,270 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to recurrence: 4,270 days (11.7 years).
- Days to follow up: 4,702 days (12.9 years); Disease response: Tumor Free.
- Karnofsky performance status: 90; ECOG performance status: 0; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -2: Lactate Dehydrogenase 294; Alpha Fetoprotein 4; Human Chorionic Gonadotropin 6.2.
- Day 73: Lactate Dehydrogenase 274; Alpha Fetoprotein 5; Human Chorionic Gonadotropin 0.1.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Did not attempt to reproduce; Risk factors: Undescended Testis; Undescended testis corrected: Yes; Undescended testis corrected age range: 10-14 years; Undescended testis corrected laterality: Right; Undescended testis corrected method: Orchiopexy; Undescended testis history: Yes; Undescended testis history laterality: Right.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2G-AAFE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 40 mg.
  Slide TCGA-2G-AAFE-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-2G-AAFE-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAFE-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; History of undescended testis: Yes, right testicle only; Level of non descent: Inguinal; History hypospadias: No; Tumor status: Tumor free.
- Primary pathology: Submitted tumor site: Testes; Bilateral diagnosis timing type: Metachronous; Testis tumor macroextent: Involves testis only; Intratubular germ cell neoplasm: Present; Lymphovascular invasion: Yes; Post orchi lymph node dissection: No; First treatment success: No Measureable Tumor or Tumor Markers.
- Primary pathology, Histology list, Histology: Histologic diagnosis: Seminoma, NOS.
- Primary pathology, Pre orchi serum marker info: Pre orchi LDH: 294; Pre orchi hcg: 6.2; Pre orchi afp: 4.
- Primary pathology, Post orchi serum marker info: Post orchi LDH: 274; Post orchi hcg: 0.1; Post orchi afp: 5.
- Primary pathology, Molecular test result list: Molecular test result: Lactate Dehydrogenase (LDH) - Normal; Molecular test result: Human Chorionic Gonadotropin (HCG) - Normal; Molecular test result: Alpha Fetaprotein (AFP) - Normal.
- Follow-up form: Lost to follow-up: No; Post orchi lymph node dissection: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.
- Drug treatment 2: Pharmaceutical therapy drug name: Ifosfamid.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Testicle; Other malignancy histological type: SE (10%), MTI (40%), EC (30%), YST (20%); Days from index date to other malignancy diagnosis: -5177.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Patient recieved chemotherapy (Bleomycine, Etoposide, and Cisplatin) for the prior maligancy (opposite testicle).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 4,702 days; disease-specific survival: no event (censored), 4,702 days; disease-free interval: event (new tumor event after initially disease-free), 617 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 617 days.
